Somatic mutation profile of tumor specimen 0DMWTT from CCDI case PBCAZK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.4 years (1,226 days).
Specimen 0DMWTT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54d3f74e-15e2-420b-9da3-b6200223a8f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMWU1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2fd9804-60f6-44c3-a54d-1367c7b6f530

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FERMT3 | c.1770G>C p.K590N (on ENST00000279227 / NM_178443.3; = p.K586N on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 204/536 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1247853574; called by muse, mutect2, varscan2
- SCNN1G | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.027); catalogued as COSV55597390; called by muse, mutect2
- SPTB | c.6068C>T p.A2023V | Missense Mutation (SNP) | VAF 37/442 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs367841692, CM941301; called by muse, mutect2
- FAM120C | c.627G>A p.P209= | Silent (SNP) | VAF 30/334 reads (9%) | catalogued as rs1364609212, COSV60259187; called by muse, mutect2
- IDS | c.-4C>T | 5'UTR (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- SVIL | c.4634-77G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
